Gene-level copy-number profile of tumor specimen ALCH-B24O-TTP1-A from ALCHEMIST case ALCH-B24O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 43.2 years (15,790 days).
Specimen ALCH-B24O-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aac0bcbd-3c1a-471e-837a-053cb71da166.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B24O-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,249 have no estimate.
https://portal.gdc.cancer.gov/files/94ea0134-724c-41f1-bd1c-e224ae5cddea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 251; copy number 2: 56,643; copy number 3: 1,346; copy number 4: 58; copy number 5: 35; copy number 6: 34; copy number 12: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 76 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,238,286–7,290,402, 7 genes, copy number 12: AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P.
- chr15:21,405,401–21,981,245, 30 genes, copy number 5: POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr19:39,863,323–40,629,818, 34 genes, copy number 6: FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4.
- chr20:22,547,671–22,585,455, 2 genes, copy number 5: LINC00261, FOXA2.
- chr20:23,362,182–23,421,519, 3 genes, copy number 5: GZF1, NAPB, RNA5SP479.

Autosomal genes at a single copy (total copy number 1): 250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
